Somatic mutation profile of tumor specimen TCGA-A2-A1FW-01A (aliquot TCGA-A2-A1FW-01A-11D-A13L-09) from TCGA case TCGA-A2-A1FW, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 62.4 years (22,779 days).
Specimen TCGA-A2-A1FW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ccda9b40-b9f8-4200-ac65-122c2f7ba47b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A2-A1FW-10A (Blood Derived Normal), aliquot TCGA-A2-A1FW-10A-01D-A13O-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/88c8dbf3-7564-4f25-8886-aa4249322ac8

The open-access MAF lists 74 somatic variants for this specimen: 51 protein-altering or splice-affecting, 22 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 22, Nonsense Mutation 4, Splice Site 2, Frame Shift Del 2, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABHD2 | c.134A>G p.Y45C | Missense Mutation (SNP) | VAF 86/169 reads (51%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.599); catalogued as rs777916601, COSV100756353; called by muse, mutect2, varscan2
- ADAMTS9 | c.5698T>C p.S1900P | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.718); catalogued as COSV55781132; called by muse, mutect2, varscan2
- AIMP1 | c.271A>G p.M91V | Missense Mutation (SNP) | VAF 45/149 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs770399051, COSV63638449; called by muse, mutect2, varscan2
- CACHD1 | c.3625C>T p.P1209S | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.968); catalogued as COSV51553370; called by muse, mutect2, varscan2
- CACNA1S | c.5504G>A p.G1835E | Missense Mutation (SNP) | VAF 32/283 reads (11%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV62939586; called by muse, mutect2, varscan2
- CACNA1S | c.4707G>T p.E1569D | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100755122; called by muse, varscan2
- CCDC80 | c.2431C>T p.R811C | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1489458675, COSV52814970; called by muse, mutect2, varscan2
- CDK5RAP1 | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV59426917; called by muse, mutect2, varscan2
- CEP152 | c.3410C>A p.P1137H | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.569); catalogued as COSV57859505; called by muse, mutect2, varscan2
- DUOX1 | c.3636C>A p.H1212Q | Missense Mutation (SNP) | VAF 68/258 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); catalogued as COSV58480924; called by muse, mutect2, varscan2
- F2RL3 | c.940G>A p.A314T | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.59); PolyPhen benign (0.013); catalogued as rs201593664; called by muse, mutect2, varscan2
- FAM71D | c.701T>G p.F234C | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as COSV61295576; called by muse, mutect2, varscan2
- GLI2 | c.1108G>A p.A370T | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.73); PolyPhen benign (0.022); catalogued as rs199931941, COSV58042133; called by muse, mutect2, varscan2
- HECTD1 | c.3102C>G p.Y1034* | Nonsense Mutation (SNP) | VAF 40/189 reads (21%) | catalogued as COSV67946350; called by muse, mutect2, varscan2
- HUWE1 | c.1583T>C p.I528T | Missense Mutation (SNP) | VAF 30/175 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV53345799; called by muse, mutect2, varscan2
- JAK3 | c.3230G>T p.C1077F | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71686058; called by muse, mutect2, varscan2
- KIAA1109 | c.895G>T p.E299* | Nonsense Mutation (SNP) | VAF 40/173 reads (23%) | catalogued as COSV52673429; called by muse, mutect2, varscan2
- KRTAP6-3 | c.247G>A p.G83S | Missense Mutation (SNP) | VAF 68/247 reads (28%) | PolyPhen probably damaging (0.917); catalogued as COSV66962917; called by muse, mutect2, varscan2
- LDB3 | c.1520C>T p.T507I | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV53941539; called by muse, mutect2, varscan2
- MRC2 | c.4037A>G p.N1346S | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.696); catalogued as COSV57639848; called by muse, mutect2
- MYO5A | c.3638C>A p.S1213* | Nonsense Mutation (SNP) | VAF 50/225 reads (22%) | catalogued as COSV62560304; called by muse, mutect2, varscan2
- NCKAP1 | c.1168G>T p.D390Y | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV62941199; called by muse, mutect2, varscan2
- NIPAL1 | c.1123G>A p.A375T | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.58); PolyPhen benign (0.006); catalogued as COSV55006568; called by muse, mutect2, varscan2
- NUDCD1 | c.1152G>C p.M384I | Missense Mutation (SNP) | VAF 118/366 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV53457026; called by muse, mutect2, varscan2
- OR1A1 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 43/140 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58403743; called by muse, mutect2, varscan2
- PDCD1 | c.105dup p.T36Hfs*70 | Frame Shift Ins (INS) | VAF 10/50 reads (20%) | catalogued as rs768249210; called by mutect2, varscan2
- PIGA | c.152G>A p.S51N | Missense Mutation (SNP) | VAF 59/146 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.261); catalogued as COSV61237631; called by muse, mutect2, varscan2
- PLIN4 | c.2180C>T p.A727V (on ENST00000301286; = p.A742V on NM_001367868.2) | Missense Mutation (SNP) | VAF 26/190 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs202029971, COSV56687242; called by muse, mutect2, varscan2
- PREX2 | c.2576G>A p.S859N | Missense Mutation (SNP) | VAF 36/227 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV55770569; called by muse, mutect2, varscan2
- RFX1 | c.2009T>G p.L670R | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV54329977; called by muse, mutect2, varscan2
- SIL1 | c.864+1G>C p.X288_splice | Splice Site (SNP) | VAF 54/74 reads (73%) | catalogued as COSV99498235; called by muse, mutect2, varscan2
- SLC2A7 | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.542); catalogued as COSV68901731; called by muse, mutect2, varscan2
- SLC45A2 | c.855G>A p.M285I | Missense Mutation (SNP) | VAF 50/239 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs756574797, COSV56871921; called by muse, mutect2, varscan2
- SYNE2 | c.15141T>G p.I5047M | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV59951222; called by muse, mutect2, varscan2
- TBC1D21 | c.412G>T p.V138F | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.445); catalogued as COSV55995351; called by muse, mutect2, varscan2
- TBC1D8B | c.2237T>C p.I746T | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52178906; called by muse, mutect2, varscan2
- TCEAL9 | c.260T>G p.L87R | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV65488995; called by muse, mutect2, varscan2
- TDRD6 | c.4751A>T p.Y1584F | Missense Mutation (SNP) | VAF 36/196 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV60175796; called by muse, mutect2, varscan2
- TESC | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 28/193 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.406); catalogued as COSV58811960; called by muse, mutect2, varscan2
- TLR4 | c.283G>T p.D95Y (on ENST00000355622 / NM_138554.5; = p.D55Y on NM_003266.4) | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV62923294; called by muse, mutect2, varscan2
- TMEM184B | c.209G>T p.R70L | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.143); catalogued as COSV100725997; called by muse, mutect2
- TNKS1BP1 | c.1642C>G p.P548A | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.04); catalogued as COSV64100093; called by muse, mutect2
- TSHZ2 | c.2729C>T p.T910M | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs367984099; called by muse, mutect2, varscan2
- TTN | c.9312G>C p.K3104N (on ENST00000591111; = p.K3058N on NM_003319.4) | Missense Mutation (SNP) | VAF 21/93 reads (23%) | PolyPhen benign (0.079); catalogued as COSV60067765; called by muse, mutect2, varscan2
- USH1C | c.778G>T p.E260* | Nonsense Mutation (SNP) | VAF 32/210 reads (15%) | catalogued as COSV50018246; called by muse, mutect2, varscan2
- VILL | c.2141C>T p.P714L | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs140199753; called by muse, mutect2, varscan2
- ZNF507 | c.2127+2T>C p.X709_splice | Splice Site (SNP) | VAF 22/63 reads (35%) | catalogued as rs770816830, COSV61331332; called by muse, mutect2, varscan2
- FURIN | c.1492C>A p.R498S | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GATA3 | c.1275_1282del p.S426Vfs*78 | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | called by mutect2, pindel
- SLC39A2 | c.55_58del p.T19Wfs*24 | Frame Shift Del (DEL) | VAF 49/218 reads (22%) | called by mutect2, pindel, varscan2
- WNK2 | c.2279C>T p.P760L | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CHGA | c.360G>A p.A120= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as rs755288105, COSV53663311; called by muse, mutect2, varscan2
- CHRM3 | c.1035C>A p.S345= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV55089422, COSV55101595; called by muse, mutect2
- CNTNAP1 | c.531C>T p.F177= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as rs763570245, COSV52850612; called by muse, mutect2, varscan2
- COL1A2 | c.411T>A p.P137= | Silent (SNP) | VAF 27/66 reads (41%) | catalogued as COSV51958227; called by muse, mutect2, varscan2
- DISC1 | c.1170G>T p.L390= | Silent (SNP) | VAF 28/155 reads (18%) | catalogued as COSV54407529, COSV99698364; called by muse, mutect2, varscan2
- DPEP3 | c.813G>A p.S271= | Silent (SNP) | VAF 18/101 reads (18%) | catalogued as rs773026799, COSV52051305; called by muse, mutect2, varscan2
- IGLV3-22 | c.252C>T p.T84= | Silent (SNP) | VAF 13/40 reads (33%) | called by muse, mutect2, varscan2
- LVRN | c.1347T>A p.I449= | Silent (SNP) | VAF 27/126 reads (21%) | catalogued as COSV63497211; called by muse, mutect2, varscan2
- MEGF8 | c.3027C>T p.F1009= (on ENST00000251268 / NM_001271938.2; = p.F942= on NM_001410.3) | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as COSV52085002; called by muse, mutect2, varscan2
- MUC17 | c.9639A>G p.P3213= | Silent (SNP) | VAF 72/201 reads (36%) | catalogued as COSV60288868; called by muse, mutect2, varscan2
- MYO18A | c.5274G>A p.L1758= | Silent (SNP) | VAF 52/968 reads (5%) | catalogued as COSV62865359; called by muse, mutect2
- NR1D2 | c.921C>T p.S307= | Silent (SNP) | VAF 24/91 reads (26%) | catalogued as COSV56991950; called by muse, mutect2, varscan2
- ODF3L2 | c.795G>A p.S265= | Silent (SNP) | VAF 15/29 reads (52%) | catalogued as rs1222143307, COSV52744937; called by muse, mutect2, varscan2
- OR2G2 | c.723C>T p.F241= | Silent (SNP) | VAF 19/175 reads (11%) | catalogued as rs765219287, COSV60740172; called by muse, mutect2, varscan2
- PAK5 | c.345C>T p.H115= | Silent (SNP) | VAF 31/125 reads (25%) | catalogued as rs780125410, COSV62027678; called by muse, mutect2, varscan2
- PCNX4 | c.3012T>G p.P1004= (on ENST00000406854 / NM_001330177.2; = p.P770= on NM_022495.5) | Silent (SNP) | VAF 19/86 reads (22%) | catalogued as COSV58304207; called by muse, mutect2, varscan2
- SART1 | c.1719C>T p.G573= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as COSV56711668; called by muse, mutect2, varscan2
- SEMA3D | c.993C>T p.L331= | Silent (SNP) | VAF 12/77 reads (16%) | catalogued as COSV52393585; called by muse, mutect2, varscan2
- SIGLEC1 | c.135C>T p.F45= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV52463905; called by muse, mutect2
- SLC6A1 | c.606C>T p.D202= | Silent (SNP) | VAF 18/115 reads (16%) | catalogued as rs146894194, COSV55112917; called by muse, mutect2, varscan2
- ZNF251 | c.1629C>T p.H543= | Silent (SNP) | VAF 17/125 reads (14%) | catalogued as rs781553257, COSV52956379; called by muse, mutect2, varscan2
- ZNF648 | c.1359C>T p.C453= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as COSV60570958, COSV60571973; called by muse, mutect2, varscan2
- AMDHD2 | c.*987T>A | 3'UTR (SNP) | VAF 42/178 reads (24%) | catalogued as COSV53550759; called by muse, mutect2, varscan2
